CCDI case PBCJCR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/90c93b29-63e8-403a-b80d-80bae293e634

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; Tissue or organ of origin: Pancreatic duct; Age at diagnosis: 4.6 years (1,671 days).

Biospecimens (3 samples)
- Sample 0DU4UM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU4V1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU4VF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
